Surgical pathology report (de-identified scan), TCGA case TCGA-FV-A2QQ, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-FV-A2QQ-01A (Primary Tumor).

[page 1 of 3]
Patient Results

SURGICAL PATHOLOGY REPORT

ACCESSION NO. :

Final Diagnosis(es):

(A) Lymph node, biopsy:

1) Vascularized fibroadipose tissue with no histopathologic abnormality.

2) No lymphoid tissue present.

(B) Gallbladder, cholecystectomy:

1) Chronic cholecystitis with cholelithiasis.

2) One periductal lymph node, negative for metastatic malignancy (0/1).

(C) Liver, biopsy:

1) Moderate steatosis.

2) No evidence of steatohepatitis.

2) Cirrhosis (Stage IV fibrosis), confirmed by the trichrome stain.

• (D) Liver, mass-segments 4 and 5, partial hepatectomy:

1) Hepatocellular carcinoma.

2) The tumor measures 7.0 cm in greatest dimension.

3) The tumor extends to within 1 millimeter of the surgical margin of resection.

4) Pathologic stage: pT1N1. ✓

3) See Synoptic Report below.

COMMENTS:

Synoptic Report:

Specimen: Liver

Procedure: Partial hepatectomy (segments 4 & 5)

Tumor Size: 7.0 cm in greatest dimension

Tumor focality: Solitary (Segments 4 & 5)

Histologic type: Hepatocellular carcinoma ✓

Histologic grade: Grade II, moderately differentiated ✓

Tumor extension: Tumor confined to the liver.

Margins:

Parenchymal margin: tumor is within 1 mm of the inked surgical parenchymal margin

Lymphovascular invasion:

Macroscopic/large vessel invasion: not identified.

Microscopic/small vessel invasion: not identified.

Pathologic stage: pT1N1.

Regional lymph nodes examined: one (1) ✓

Regional lymph nodes involved by tumor: none (0)

Additional findings: Cirrhosis.

The gross description and all microscopic slides have been reviewed and interpreted by the undersigned pathologist'

Electronically Signed

M.D. (Resident)

Specimen(s) Received:

A: Lymph node

B: Gallbladder

C: Liver biopsy

ICA-0-3

carcinoma, hepatocellular, nos 8170/3

Site liver c22.0

pw
9/3/11

[page 2 of 3]
Patient Results

D: Liver mass

Clinical History:

Hepatocellular carcinoma.

Intraoperative Consultation:

Time Received: 14:50

Time Reported: 15:10

D: Liver mass: Approximately 1 mm from margin (0 blocks)
(Gross examination only).

MD

M.D. (Resident)

Gross Description:

(A) (lymph node) Received in formalin are two fragments of yellow-tan firm tissue measuring 0.4 x 0.3 x 0.2 cm and 1.5 x 0.7 x 0.5 cm. The smaller specimen is inked black and submitted entirely in A1 along with the larger specimen, which is uninked and bisected.

(B) (gallbladder) Received in formalin is a previously unopened 9.4 x 5.0 x 5.0 cm gallbladder. The serosal surfaces are purple-tan and glistening. The gallbladder has a wall measuring 0.2 cm. The mucosal surfaces are green and velvety. The gallbladder contains green bile and four large firm yellow stones ranging in size from 1.5 x 1.5 x 0.5 cm up to 3.5 x 3.5 x 2.8 cm. A cross-section of the cystic duct and a representative section of the wall are submitted in B1 along with a section of a 1.5 cm greatest dimension lymph node candidate.

(C) (liver biopsy) Received in formalin are two tan tissue cores measuring 0.1 cm in diameter and ranging in length from 0.4 to 2.1 cm. The specimen is submitted entirely in C1.

(D) (liver mass) Received fresh for intraoperative consultation is a 10.0 x 6.0 x 4.0 cm portion of liver. One side is cauterized and the capsular surface is gray-tan with a smooth serosa but a macronodular surface. The resection margin is inked black. Sectioning through the specimen reveals a yellow lobulated soft tissue mass measuring 7.0 x 5.0 x 3.0 cm and appears to abut the surgical resection margin but does not appear to penetrate through it. Representative sections are submitted in D1-D5 with D1-D2 containing tumor to the closest resection margin. A representative section of grossly uninvolved liver is submitted in D6.

Microscopic Description:

Complete microscopic evaluation has been performed.

Appropriately reacting controls have been performed and evaluated for all stains on this case as required.

Histopathology has a list of IH antibodies that are regulated as analyte specific reagents (ASR's). These assays were developed and their performance characteristics determined by the Histopathology Laboratory in the _____ at the _____.

They have not been cleared by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary for the ASR's. These

[page 3 of 3]
Patient Results

tests are not investigational and are used in standard clinical care. In cases where Immunohistochemistry testing is performed, the following antibodies and their respective clones may be used to determine therapy for the patient: EFGR(31G7), ER(SP1), PR(1E2), Her2neu(4B5), CD117(Poly), CD20(L26).

Unless otherwise stated in the report, all tissue tested for ERPR by IHC, Her2 by IHC and/or HER2 by FISH have been fixed as per ANP.22998 for a minimum of 6 hours and a maximum of 48 hours.

ER, PR, Ki-67, p53 are reported as a semi-quantitative percentage of positively stained nuclei. Her-2/neu and EGFR are scored as follows: No staining at all is scored as (0), weak, incomplete membrane staining in any proportion of cells is scored as (1+), less than strong but complete staining in any proportion of cells or complete strong staining in less than 30% of cells is scored as (2+), and strong complete staining in more than 30% of cells is scored as (3+). All studies are performed on tissue fixed in 10% neutral buffered formalin and embedded in paraffin unless otherwise stated in the report.

Source: NCI Genomic Data Commons file 38eba28e-9981-447c-95bf-80da176e4f52 (TCGA-FV-A2QQ.350B10AF-C17B-41DA-BB21-A672DBB683B2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).